FM case AD9176 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/c67f90bf-2806-46c2-9fd4-ebac6db99a74

Male, 39.0 years: Papillary renal cell carcinoma (ICD-O-3 8260/3) of the kidney; metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
